Somatic mutation profile of tumor specimen TCGA-RW-A8AZ-01A (aliquot TCGA-RW-A8AZ-01A-11D-A35D-08) from TCGA case TCGA-RW-A8AZ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 66.4 years (24,268 days).
Specimen TCGA-RW-A8AZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc57dbeb-05e5-4a02-9314-e308b4f0aedc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A8AZ-10A (Blood Derived Normal), aliquot TCGA-RW-A8AZ-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fbcb0a5-7f0a-4c58-b1c6-c333564d1c14

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 18, Silent 9, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA2 | c.2606C>T p.A869V (on ENST00000614293; = p.A839V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.923); catalogued as rs1271207716, COSV99687340; called by muse, mutect2, varscan2
- CDK5RAP1 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs370504202; called by muse, mutect2, varscan2
- COL12A1 | c.1406G>T p.S469I | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV59389275; called by muse, mutect2, varscan2
- DVL2 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0.378); catalogued as rs147610025; called by muse, mutect2, varscan2
- FOXI2 | c.756G>A p.M252I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs766546220; called by muse, varscan2
- PRKAR1A | c.503-2A>G p.X168_splice | Splice Site (SNP) | VAF 59/164 reads (36%) | catalogued as rs1392621681; called by muse, mutect2, varscan2
- R3HDML | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs539665398, COSV53835590; called by muse, mutect2, varscan2
- TRIM17 | c.1081G>T p.G361W | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99488969; called by muse, mutect2, varscan2
- URM1 | c.95A>T p.Q32L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100864858; called by muse, mutect2, varscan2
- WT1 | c.739C>A p.H247N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.071); catalogued as COSV60081889; called by muse, mutect2, varscan2
- ZNF687 | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1440477352, COSV55021034; called by muse, mutect2, varscan2
- ATRX | c.2914_2917del p.D972Rfs*30 | Frame Shift Del (DEL) | VAF 143/188 reads (76%) | called by mutect2, pindel, varscan2
- BICD1 | c.1185G>C p.K395N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- BIRC6 | c.5634C>G p.Y1878* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- DUOX2 | c.4582A>G p.K1528E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- EPHA3 | c.2092G>A p.V698I | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FAT1 | c.11807C>A p.T3936K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (1); PolyPhen probably damaging (0.928); called by muse, varscan2
- HDHD5 | c.776T>C p.L259P (on ENST00000336737 / NM_033070.3; = p.L229P on NM_017829.5) | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IWS1 | c.961T>C p.S321P | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAML3 | c.2518C>T p.P840S | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MUC16 | c.40557C>G p.F13519L | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PAPOLA | c.1803del p.Q601Hfs*22 | Frame Shift Del (DEL) | VAF 82/230 reads (36%) | called by mutect2, pindel, varscan2
- ATP2A1 | c.1752C>T p.F584= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs1396282450; called by muse, mutect2, varscan2
- CCDC110 | c.1932T>C p.L644= | Silent (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- CNTNAP3 | c.2085A>G p.G695= | Silent (SNP) | VAF 53/140 reads (38%) | catalogued as rs1255954668, COSV99905170; called by muse, mutect2, varscan2
- KLF12 | c.858A>G p.Q286= | Silent (SNP) | VAF 65/160 reads (41%) | catalogued as rs776350957; called by muse, mutect2, varscan2
- KLHL36 | c.1236T>A p.S412= | Silent (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2, varscan2
- NRROS | c.723C>T p.F241= | Silent (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- SHISA3 | c.663C>G p.L221= | Silent (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- TMEM8B | c.1029C>G p.L343= | Silent (SNP) | VAF 64/150 reads (43%) | called by muse, mutect2, varscan2
- YME1L1 | c.1743T>G p.P581= (on ENST00000326799 / NM_139312.3; = p.P524= on NM_014263.4) | Silent (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
